Surgical pathology report (de-identified scan), TCGA case TCGA-55-8204, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8204-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type: Surgical Pathology Report
Result date: [REDACTED]
Result status: Signed
Result title: Surgical Pathology Report
Performed by: [REDACTED]
Verified by: [REDACTED]
Encounter info: [REDACTED]

* Final Report *

Clinical History

Left upper lobe lung cancer

Specimen

- #1 Station 7 lymph node
- #2 Station 7 lymph node #2
- #3 4L lymph node
- #4 4R lymph node
- #5 Left upper lobe nodule
- #6 Level 6 lymph node, left lung
- #7 Level 10 lymph node, left lung

Gross Examination

- #1 Received fresh labeled as station 7 lymph node is a portion of tan-brown tissue measuring 0.4 x 0.3 x 0.2 cm with no gross lesion, submitted in toto, frozen section, one block.
- #2 Received fresh labeled as station 7 lymph node #2 are two portions of tan-black tissue measuring in aggregate 0.5 x 0.3 x 0.2 cm, submitted in toto, frozen section, one block.
- #3 Received fresh labeled as 4L lymph node are five portions of tan-black tissue measuring in aggregate 1.1 x 0.6 x 0.2 cm, submitted in toto, frozen section, one block.
- #4 Received fresh labeled as 4R lymph node are two portions of tan-brown tissue measuring in aggregate 0.8 x 0.5 x 0.2 cm, in toto, one cassette for frozen. [REDACTED]
- #5 Received fresh for frozen section labeled left upper lobe wedge is a 10.6 x 7.2 x 3.0 cm lung wedge resection with red-purple, finely nodular pleura. The pleura is focally retracted over an ill-defined 2.7 x 2.0 x 1.2 cm gray-brown, firm mass. The mass abuts the overlying pleura (with central aforementioned retraction) and is 0.9 cm from the closest stapled parenchymal margin. A representative section of the nodule and the closest staple margin are frozen ("5FSA and 5FSB" respectively). The remainder of the parenchyma is soft, red, and spongy with prominent emphysematous change. No additional mass lesions are identified. Representative

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surgical Pathology Report

* Final Report *

fresh tumor and normal parenchyma are procured for the Genome Study following signed consent. Five sections are submitted in five: "A"- "E". Block summary: "A", "B" mass with respect to pleura, perpendicular (pleura inked black); "C" mass with respect to adjacent parenchyma; "D", "E" parenchyma with emphysematous change.

#6 Labeled level 6 lymph node are two fragments of pink-tan to black tissue that measure from 0.5 x 0.5 x 0.2 cm up to 0.8 x 0.5 x 0.3 cm. In toto one cassette.

#7 Labeled level 10 lymph node. There is a single fragment of pink-tan to black tissue that measures 1.7 x 0.3 x 0.2 cm. In toto one cassette.

Frozen Section Diagnosis

#1 MEDIASTINAL LYMPH NODE, LEVEL 7, EXCISION (1 FS): NEGATIVE FOR CARCINOMA.

#2 MEDIASTINAL LYMPH NODE, LEVEL 7 #2, EXCISION (1 FS): NEGATIVE FOR CARCINOMA.

#3 MEDIASTINAL LYMPH NODE, 4L, EXCISION (1 FS): NEGATIVE FOR CARCINOMA.

#4 MEDIASTINAL LYMPH NODE, 4R, EXCISION (1 FS): NEGATIVE FOR CARCINOMA.

#1-4 REPORTED TO [REDACTED] BY [REDACTED] AT [REDACTED]

#5 LUNG, LEFT UPPER LOBE, NODULE, WEDGE RESECTION (2 FS): POORLY DIFFERENTIATED

NON-SMALL CELL CARCINOMA. CLOSEST STAPLED MARGIN OF RESECTION NEGATIVE FOR CARCINOMA.
REPORTED TO DR. [REDACTED]

Microscopic Examination

#1-#7 Microscopic examination performed. The tumor is poorly differentiated with a background fibrous and inflamed stroma. Scattered lumens with clusters of neutrophils are present. Immunohistochemical stains are performed on block "5B" of the tumor and show the malignant cells are positive for TTF-1, CK7, and p63. The malignant cells are negative for CK20. The overall morphologic and immunohistochemical findings are most consistent with adenocarcinoma of primary lung origin. Elastin stains performed on blocks "5A" and "5B" confirm the tumor invades to the visceral pleural surface. Select slides are reviewed with Dr. [REDACTED]

Final Diagnosis

#1 LYMPH NODE, STATION 7, EXCISION: NEGATIVE FOR CARCINOMA.

#2 LYMPH NODE, STATION 7(#2), EXCISION: NEGATIVE FOR CARCINOMA.

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

- #3 LYMPH NODE, 4L, EXCISION: NEGATIVE FOR CARCINOMA.
#4 LYMPH NODE, 4R, EXCISION: NEGATIVE FOR CARCINOMA.
#5 LUNG, LEFT UPPER LOBE, WEDGE RESECTION: POORLY DIFFERENTIATED NON SMALL CELL

CARCINOMA, CONSISTENT WITH ADENOCARCINOMA.

TUMOR SIZE: 2.7 X 2.0 X 1.2 CM.

PLEURAL SURFACE STATUS: CARCINOMA INVADES TO THE VISCERAL PLEURAL SURFACE.

LYMPHOVASCULAR SPACE STATUS: NEGATIVE FOR LYMPHOVASCULAR SPACE INVASION.

ADDITIONAL PATHOLOGIC FINDINGS: EMPHYSEMATOUS CHANGES.

STAPLED SURGICAL MARGIN OF RESECTION: NEGATIVE FOR CARCINOMA.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT2a PL2 pN0.

- #6 LYMPH NODE, LEVEL 6, EXCISION: NEGATIVE FOR CARCINOMA.
#7 LYMPH NODE, LEVEL 10, EXCISION: NEGATIVE FOR CARCINOMA.

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file d16f9968-7f82-4ad6-91cf-36a819ed9d87 (TCGA-55-8204.E3A193F9-F815-4BD4-B5F5-0329D7D6E845.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).